Gene-level copy-number profile of tumor specimen CDDP-ACIV-TTP1-A from CDDP_EAGLE case CDDP-ACIV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65 years.
Specimen CDDP-ACIV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb002957-8c94-48f7-8374-c35d40f31c32.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACIV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/b057b2b4-0a20-4550-87bc-aae24a5dbf98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,646; copy number 2: 53,632; copy number 3: 1,549; copy number 4: 58; copy number 5: 2; copy number 6: 7; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:7,855,066–7,856,099, 1 gene: TMEM88.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,940,341–56,944,353, 1 gene, copy number 9: AC069152.1.
- chr9:39,355,669–39,508,885, 7 genes, copy number 6: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr16:75,218,988–75,226,338, 1 gene, copy number 5 (within-gene range 2–5): CTRB1.
- chr16:81,030,770–81,031,485, 1 gene, copy number 5 (within-gene range 2–5): AC092718.4.

Autosomal genes at a single copy (total copy number 1): 790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
